Somatic mutation profile of tumor specimen TCGA-BJ-A45H-01A (aliquot TCGA-BJ-A45H-01A-12D-A23U-08) from TCGA case TCGA-BJ-A45H, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 45.3 years (16,541 days).
Specimen TCGA-BJ-A45H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f81048f-bd9a-4f06-aab0-8eb05c946d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45H-10A (Blood Derived Normal), aliquot TCGA-BJ-A45H-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ac3f50b-39ea-40a8-ac29-e8924bb32a80

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AK9 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV99572790; called by muse, mutect2, varscan2
- NPAS2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.23); catalogued as rs1423558314, COSV100177004; called by muse, mutect2
- SIPA1L1 | c.1942C>G p.R648G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100666081, COSV62170051, COSV62173814; called by muse, mutect2
- TCF7L2 | c.697C>T p.P233S (on ENST00000355995 / NM_001367943.1; = p.P210S on NM_030756.5) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV99526718; called by muse, mutect2, varscan2
- TXNL1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 8/137 reads (6%) | catalogued as COSV99469906; called by muse, mutect2
- CDH23 | c.1472_1482del p.T491Sfs*7 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- CHD7 | c.3021C>T p.L1007= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as COSV101418463; called by muse, mutect2, varscan2
